Somatic mutation profile of tumor specimen HCM-BROD-0223-C43-06A (aliquot HCM-BROD-0223-C43-06A-11D-A78T-36) from HCMI case HCM-BROD-0223-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.2 years (26,743 days).
Specimen HCM-BROD-0223-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40442f69-d8a9-406f-b58a-6e56510b2377.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0223-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0223-C43-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54e326c0-752f-45f4-a455-9e68a8787599

The open-access MAF lists 2,649 somatic variants for this specimen: 1,536 protein-altering or splice-affecting, 780 silent, 333 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,376, Silent 780, Intron 147, Nonsense Mutation 89, RNA 59, 3'UTR 51, Splice Region 31, 5'Flank 30, 5'UTR 28, Splice Site 20, 3'Flank 17, Frame Shift Del 14.

Variants (750 of 2,649; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.9175C>T p.R3059C | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs146377316, CM127717, COSV51947017; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ATP8B3 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 149/392 reads (38%) | catalogued as rs568761860; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB4 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 87/251 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs202247795, COSV104368601, COSV53499570; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNA11 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 89/291 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555702147, COSV50017316; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KIT | c.2466T>A p.N822K | Missense Mutation (SNP) | VAF 57/124 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MYL2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 169/416 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs104894368, CM961005, COSV57405974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1070T>C p.L357P | Missense Mutation (SNP) | VAF 122/292 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs137854563, CM000777; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 159/388 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as COSV61982533; called by muse, mutect2, varscan2
- RBM20 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 90/203 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397516607, COSV65706173, COSV65707634; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1327G>A p.G443R (on ENST00000373993 / NM_138932.2; = p.G435R on NM_014576.4) | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.368); catalogued as rs1261105378; called by muse, mutect2, varscan2
- A1CF | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV50985594; called by muse, mutect2, varscan2
- A4GNT | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 92/236 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1052933001; called by muse, mutect2, varscan2
- ABCA13 | c.14320A>G p.T4774A | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV68946828; called by muse, mutect2, varscan2
- ABCA2 | c.6778C>T p.L2260F (on ENST00000614293; = p.L2230F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/175 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs1364115511; called by muse, mutect2, varscan2
- ABCA3 | c.5011G>A p.E1671K | Missense Mutation (SNP) | VAF 206/549 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as COSV57060928; called by muse, mutect2, varscan2
- ABCA4 | c.2734G>A p.G912R | Missense Mutation (SNP) | VAF 123/369 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1216408517, COSV64675475; called by muse, mutect2, varscan2
- ABCA7 | c.5018C>T p.S1673F | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV54029897; called by muse, mutect2, varscan2
- ABCC3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs578228776; called by muse, mutect2, varscan2
- ABCC3 | c.4146G>A p.M1382I | Missense Mutation (SNP) | VAF 95/208 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); catalogued as rs750587507, COSV53325337; called by muse, mutect2, varscan2
- ABCG2 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs561273590, COSV52945155; called by muse, mutect2, varscan2
- AC006059.2 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 93/260 reads (36%) | catalogued as rs186928386; called by muse, mutect2, varscan2
- ACAN | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as COSV100718122; called by muse, mutect2, varscan2
- ACBD3 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 138/328 reads (42%) | catalogued as COSV64729752; called by muse, mutect2, varscan2
- ACCSL | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 119/154 reads (77%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as rs199907490; called by muse, mutect2, varscan2
- ACSBG2 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 119/308 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as rs751364914; called by muse, mutect2, varscan2
- ACSM2A | c.1189G>A p.D397N (on ENST00000219054; = p.D318N on NM_001308169.2) | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs750637232, COSV54582503; called by muse, mutect2, varscan2
- ACSM2B | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV61656609; called by muse, mutect2, varscan2
- ADA | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 97/264 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs773557479, COSV65739994; called by muse, mutect2, varscan2
- ADAD1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs78087673, COSV99635305; called by muse, mutect2, varscan2
- ADAM2 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760693378; called by muse, mutect2, varscan2
- ADAM28 | c.306+8G>A | Splice Region (SNP) | VAF 50/111 reads (45%) | catalogued as rs775862538; called by muse, mutect2, varscan2
- ADAM28 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV56106893; called by muse, mutect2, varscan2
- ADAM29 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV63666064; called by muse, mutect2, varscan2
- ADAM32 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV65951006; called by muse, mutect2, varscan2
- ADAM7 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV51545300; called by muse, varscan2
- ADAMTS18 | c.2402C>T p.T801I | Missense Mutation (SNP) | VAF 253/345 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51403207; called by muse, mutect2, varscan2
- ADAMTS5 | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 77/104 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs757271994, COSV53178718; called by muse, mutect2, varscan2
- ADAMTS6 | c.3031C>T p.R1011C | Missense Mutation (SNP) | VAF 109/153 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs769190743, COSV58683484; called by muse, mutect2, varscan2
- ADAMTS9 | c.4318C>T p.P1440S | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as COSV55778775; called by muse, varscan2
- ADAMTS9 | c.4291C>T p.R1431C | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); catalogued as rs1170794686; called by muse, varscan2
- ADAMTS9 | c.2794G>A p.G932S | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as rs150178160; called by muse, mutect2, varscan2
- ADCY8 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 123/375 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.709); catalogued as rs145360233, COSV53913924; called by muse, mutect2, varscan2
- ADGB | c.4852G>A p.D1618N | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs544011156; called by muse, mutect2, varscan2
- ADGRB1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 194/505 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.734); catalogued as rs191669433; called by muse, mutect2, varscan2
- ADGRB3 | c.1572G>A p.W524* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as COSV65412416; called by muse, mutect2, varscan2
- ADGRE2 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 196/427 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.16); catalogued as COSV100216433; called by muse, mutect2, varscan2
- ADGRF5 | c.3308G>A p.W1103* | Nonsense Mutation (SNP) | VAF 100/317 reads (32%) | catalogued as COSV99346312; called by muse, mutect2, varscan2
- ADGRV1 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1045063485, COSV67989524; called by muse, mutect2, varscan2
- ADGRV1 | c.16732G>A p.D5578N | Missense Mutation (SNP) | VAF 83/107 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs747302299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFM | c.263A>T p.K88I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs181593933, COSV56920818; called by muse, mutect2, varscan2
- AGBL1 | c.489G>A p.R163= | Splice Region (SNP) | VAF 43/160 reads (27%) | catalogued as rs773202906, COSV69794090; called by muse, mutect2, varscan2
- AGXT2 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 353/388 reads (91%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV51491337; called by muse, mutect2, varscan2
- AK8 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 102/157 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100049687; called by muse, mutect2, varscan2
- AKAP17A | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.106); catalogued as COSV58309811; called by muse, mutect2, varscan2
- AKR1C1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV66499627; called by muse, mutect2, varscan2
- AKT2 | c.1266C>T p.L422= | Splice Region (SNP) | VAF 278/650 reads (43%) | catalogued as rs1568516568; called by muse, mutect2, varscan2
- ALB | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 119/298 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV55736203; called by muse, mutect2, varscan2
- ALDH1L1 | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 107/285 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553676435; called by muse, mutect2, varscan2
- ALK | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 182/456 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.863); catalogued as rs766821017, COSV66556776; called by muse, mutect2, varscan2
- ALK | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 183/499 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs267599336; called by muse, mutect2, varscan2
- ALOX15 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 24/61 reads (39%) | catalogued as COSV53398043; called by muse, mutect2, varscan2
- ALPK3 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 77/222 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs774126835, COSV51935600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMBRA1 | c.1633C>T p.P545S (on ENST00000458649 / NM_001367468.1; = p.P455S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 155/207 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs771074894; called by muse, mutect2, varscan2
- ANHX | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 243/337 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs1351202474; called by muse, mutect2, varscan2
- ANK1 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 157/473 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1427563866; called by muse, mutect2, varscan2
- ANK3 | c.4084G>A p.G1362R (on ENST00000280772 / NM_001320874.2; = p.G496R on NM_001149.3) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99777874; called by muse, mutect2, varscan2
- ANKRA2 | c.289+2T>C p.X97_splice | Splice Site (SNP) | VAF 13/17 reads (76%) | catalogued as rs1452226859; called by muse, mutect2, varscan2
- ANKRD24 | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs376089361; called by muse, mutect2, varscan2
- ANKRD30A | c.1786G>A p.G596R (on ENST00000611781; = p.G540R on NM_052997.2) | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.972); catalogued as COSV64603643; called by muse, mutect2, varscan2
- ANKRD30A | c.2500G>A p.G834R (on ENST00000611781; = p.G778R on NM_052997.2) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV64612412, COSV99071049; called by muse, mutect2, varscan2
- ANKRD62 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 84/185 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV58412962; called by muse, mutect2, varscan2
- ANO4 | c.607G>A p.D203N (on ENST00000392977 / NM_001286615.2; = p.D168N on NM_178826.4) | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs758365911, COSV54587105; called by muse, mutect2, varscan2
- ANPEP | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 109/250 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs759489673; called by muse, mutect2, varscan2
- ANXA13 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 105/230 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51623732; called by muse, mutect2, varscan2
- APC2 | c.4096C>T p.R1366C | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1361316073; called by muse, mutect2, varscan2
- APOB | c.12460G>A p.E4154K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.04); catalogued as rs767587977; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 169/428 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61266759; called by muse, mutect2, varscan2
- ARGFX | c.860T>G p.M287R | Missense Mutation (SNP) | VAF 84/221 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100544171; called by muse, mutect2, varscan2
- ARHGEF2 | c.2536C>T p.R846W (on ENST00000361247 / NM_001162383.2; = p.R818W on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1426046254, COSV100560999; called by muse, mutect2, varscan2
- ARHGEF38 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.092); catalogued as rs1342007147; called by muse, varscan2
- ARID2 | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 73/156 reads (47%) | catalogued as COSV57601825; called by muse, mutect2, varscan2
- ARID5B | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54416132; called by muse, mutect2, varscan2
- ARMC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs866196713, COSV59455677; called by muse, mutect2, varscan2
- ASCC2 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV57072882; called by muse, mutect2, varscan2
- ASIC1 | c.1206G>A p.G402= | Splice Region (SNP) | VAF 158/439 reads (36%) | catalogued as rs1201469889; called by muse, mutect2, varscan2
- ASXL2 | c.4124C>T p.P1375L | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs1255700047; called by muse, mutect2, varscan2
- ATAD5 | c.1663C>A p.L555M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.293); catalogued as COSV58972631, COSV58978300; called by muse, mutect2, varscan2
- ATP10D | c.3335A>G p.N1112S | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as rs747735220; called by muse, mutect2, varscan2
- ATP13A1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 206/504 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759381799, COSV52290232; called by muse, mutect2, varscan2
- ATP13A2 | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 128/373 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs55635527; called by muse, mutect2, varscan2
- ATP1A3 | c.2399A>G p.N800S (on ENST00000545399 / NM_001256214.2; = p.N787S on NM_152296.5) | Missense Mutation (SNP) | VAF 163/422 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV57490034; called by muse, mutect2, varscan2
- ATP8B4 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748152515, COSV52717553; called by muse, mutect2, varscan2
- ATR | c.6620C>T p.S2207F | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV63390218; called by muse, mutect2, varscan2
- AXDND1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs868380930, COSV62648005; called by muse, mutect2, varscan2
- B4GALNT1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as rs1175256509; called by muse, mutect2, varscan2
- BAIAP3 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs760205376, COSV50103879, COSV99136177; called by muse, mutect2, varscan2
- BAP1 | c.2090C>T p.S697F | Missense Mutation (SNP) | VAF 189/271 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56235708; called by muse, mutect2, varscan2
- BCL2L10 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 188/509 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs758841562; called by muse, mutect2, varscan2
- BNC1 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 145/441 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61758856; called by muse, mutect2, varscan2
- BRINP3 | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 94/250 reads (38%) | catalogued as COSV66513576, COSV66524701; called by muse, varscan2
- C19orf47 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751821059; called by muse, mutect2, varscan2
- C1QTNF9B | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65943938; called by muse, mutect2, varscan2
- C1QTNF9B | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.814); catalogued as rs752036686; called by muse, mutect2, varscan2
- C1orf87 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV64598748; called by muse, mutect2, varscan2
- C2orf78 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV68518166; called by muse, mutect2, varscan2
- C2orf80 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs267599173; called by muse, mutect2, varscan2
- C6orf15 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99456631; called by muse, varscan2
- C8A | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 275/750 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs760124872; called by muse, mutect2, varscan2
- C9 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 134/159 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs757060107, COSV54676570; called by muse, mutect2, varscan2
- CACNA1E | c.1056G>A p.G352= | Splice Region (SNP) | VAF 98/226 reads (43%) | catalogued as COSV62392543, COSV62418341; called by muse, varscan2
- CACNA1E | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 90/232 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62388732; called by muse, varscan2
- CACNA1H | c.3532G>A p.E1178K | Missense Mutation (SNP) | VAF 197/453 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as rs1396673003, COSV61992090; called by muse, mutect2, varscan2
- CALB2 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100226083, COSV56939553; called by muse, mutect2, varscan2
- CARMIL2 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 92/128 reads (72%) | catalogued as COSV58026548, COSV58027649; called by muse, mutect2, varscan2
- CASP14 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99693101; called by muse, mutect2, varscan2
- CASR | c.2764G>A p.E922K (on ENST00000490131; = p.E999K on NM_000388.4) | Missense Mutation (SNP) | VAF 250/610 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99948333; called by muse, varscan2
- CATSPERB | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.12); catalogued as rs1215491838, COSV56426370; called by muse, mutect2, varscan2
- CATSPERD | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as rs191427801; called by muse, mutect2, varscan2
- CATSPERG | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 93/266 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs140177794, COSV53048178; called by muse, mutect2, varscan2
- CBL | c.1096-2A>T p.X366_splice | Splice Site (SNP) | VAF 50/125 reads (40%) | catalogued as COSV50651087; called by muse, mutect2, varscan2
- CC2D2B | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV100729324; called by muse, mutect2, varscan2
- CCDC166 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1554616721, COSV72638820; called by muse, mutect2, varscan2
- CCDC54 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV53758288; called by muse, mutect2, varscan2
- CCDC87 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1480604332; called by muse, mutect2, varscan2
- CCDC88C | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs886916252, COSV66241642; called by muse, mutect2, varscan2
- CCDC92 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT tolerated (0.52); PolyPhen benign (0.12); catalogued as rs143142884; called by muse, mutect2, varscan2
- CCER1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs1412453346; called by muse, mutect2, varscan2
- CCKAR | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484342891, COSV55160821, COSV55164441; called by muse, mutect2, varscan2
- CCKAR | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 106/271 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs769825338; called by muse, mutect2, varscan2
- CCNQ | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 138/165 reads (84%) | catalogued as COSV52343985; called by muse, mutect2, varscan2
- CD163 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV63135893; called by muse, mutect2, varscan2
- CD2BP2 | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs748668169; called by muse, mutect2, varscan2
- CD53 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as rs190729207, COSV54761318; called by muse, mutect2, varscan2
- CD6 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.437); catalogued as rs1234192046, COSV100533134, COSV57836291; called by muse, mutect2, varscan2
- CD84 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751746966, COSV60867000; called by muse, mutect2, varscan2
- CDC6 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 121/327 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs866378978, COSV52931322; called by muse, mutect2, varscan2
- CDK13 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as rs760503314, COSV99475854, COSV99475894; called by muse, mutect2, varscan2
- CDKAL1 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV51189877; called by muse, mutect2, varscan2
- CEP162 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV57625401; called by muse, mutect2, varscan2
- CEP162 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.025); catalogued as rs138904266; called by muse, mutect2, varscan2
- CEP290 | c.2832C>A p.F944L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV58355490; called by muse, mutect2, varscan2
- CEP76 | c.1036C>T p.L346F | Missense Mutation (SNP) | VAF 105/266 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.096); catalogued as rs1169303587; called by muse, mutect2, varscan2
- CEP89 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs772026609; called by muse, mutect2, varscan2
- CES5A | c.30G>T p.Q10H | Missense Mutation (SNP) | VAF 57/86 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs567508805; called by muse, mutect2, varscan2
- CFAP74 | c.4208C>T p.S1403L | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs769266515; called by muse, mutect2, varscan2
- CFB | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 302/750 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.476); catalogued as rs1411072076; called by muse, mutect2, varscan2
- CFTR | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs144720913, CM067769, COSV50060609, COSV50129630; called by muse, mutect2, varscan2
- CHADL | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 87/209 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs1045554218; called by muse, mutect2, varscan2
- CHD8 | c.5622C>A p.F1874L (on ENST00000646647 / NM_001170629.2; = p.F1595L on NM_020920.4) | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs1301490795; called by muse, mutect2, varscan2
- CHI3L1 | c.257+2T>C p.X86_splice | Splice Site (SNP) | VAF 72/173 reads (42%) | catalogued as rs752438854; called by muse, mutect2, varscan2
- CLCN1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 124/333 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143506735, COSV58372528; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLSTN3 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs149690531; called by muse, mutect2
- CNTN5 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as COSV54343066; called by muse, mutect2, varscan2
- CNTN6 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV63167352; called by muse, mutect2, varscan2
- CNTNAP2 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV62202038; called by muse, mutect2, varscan2
- CNTNAP2 | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 153/354 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs777946931, COSV62162609; called by muse, mutect2, varscan2
- COL15A1 | c.2291G>A p.G764D | Missense Mutation (SNP) | VAF 82/111 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773801695; called by muse, mutect2, varscan2
- COL20A1 | c.3512G>A p.G1171E | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58912963; called by muse, mutect2, varscan2
- COL21A1 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 69/132 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55154545; called by muse, mutect2, varscan2
- COL3A1 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 129/336 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.057); catalogued as rs1460396340, COSV100482331; called by muse, mutect2, varscan2
- COL4A4 | c.3223G>A p.G1075S | Missense Mutation (SNP) | VAF 119/326 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100305920; called by muse, mutect2, varscan2
- COL4A6 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 73/89 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57860857; called by muse, mutect2, varscan2
- COL6A3 | c.6788G>A p.R2263Q | Missense Mutation (SNP) | VAF 257/700 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs779508804, COSV55082724, COSV55109613; called by muse, mutect2, varscan2
- COL6A3 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV55110000; called by muse, mutect2, varscan2
- COL6A6 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 106/229 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.191); catalogued as rs766329094, COSV62019088; called by muse, mutect2, varscan2
- COL7A1 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 250/333 reads (75%) | SIFT tolerated (0.22); PolyPhen benign (0.265); catalogued as COSV60395932; called by muse, mutect2, varscan2
- COL8A2 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs752761856, COSV57443475; called by muse, mutect2, varscan2
- COL9A1 | c.1631G>A p.G544D | Missense Mutation (SNP) | VAF 166/431 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1431958752, COSV100294757, COSV57878088; called by muse, mutect2, varscan2
- COLQ | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 140/404 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67524190; called by muse, varscan2
- COPZ1 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746806623; called by muse, mutect2, varscan2
- CORO7 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs1270698708, COSV52028057; called by muse, mutect2, varscan2
- COX8C | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 60/75 reads (80%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as rs199879752; called by muse, mutect2, varscan2
- CPED1 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV59997018, COSV60010339; called by muse, mutect2, varscan2
- CPO | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as rs771644753, COSV55939003; called by muse, mutect2, varscan2
- CPSF3 | c.1953G>A p.R651= | Splice Region (SNP) | VAF 53/137 reads (39%) | catalogued as rs139245590; called by muse, mutect2, varscan2
- CPT1B | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 99/304 reads (33%) | catalogued as rs374942225; called by muse, mutect2, varscan2
- CPZ | c.550C>T p.R184C (on ENST00000360986 / NM_001014447.3; = p.R173C on NM_003652.3) | Missense Mutation (SNP) | VAF 253/581 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs149059553; called by muse, mutect2, varscan2
- CRACR2A | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 125/280 reads (45%) | catalogued as COSV61543472; called by muse, mutect2, varscan2
- CREBBP | c.3323C>T p.S1108L | Missense Mutation (SNP) | VAF 187/499 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52114165, COSV52118821; called by muse, mutect2, varscan2
- CREM | c.718C>T p.P240S (on ENST00000429130; = p.P16S on NM_182717.2) | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1449034717; called by muse, mutect2, varscan2
- CRHR2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs1301686299; called by muse, mutect2, varscan2
- CRHR2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 99/212 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs146042188; called by muse, mutect2, varscan2
- CSF2RA | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 159/355 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV62625025; called by muse, mutect2, varscan2
- CSMD1 | c.6100G>A p.G2034R (on ENST00000520002; = p.G2033R on NM_033225.6) | Missense Mutation (SNP) | VAF 163/452 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59320972; called by muse, mutect2, varscan2
- CSMD1 | c.4531G>A p.G1511R (on ENST00000520002; = p.G1510R on NM_033225.6) | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59319601, COSV59337029; called by muse, mutect2, varscan2
- CSMD1 | c.3847C>T p.H1283Y (on ENST00000520002; = p.H1282Y on NM_033225.6) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as rs1482502744; called by muse, mutect2, varscan2
- CST9L | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 108/313 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65407873; called by muse, mutect2, varscan2
- CST9L | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 110/319 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV65408154; called by muse, mutect2, varscan2
- CTLA4 | c.523T>C p.F175L | Missense Mutation (SNP) | VAF 92/250 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV55593336; called by muse, mutect2, varscan2
- CXXC1 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 37/590 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.84); catalogued as rs757203610, COSV53275758; called by muse, mutect2
- CYP1A2 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV59661369; called by muse, mutect2, varscan2
- CYP24A1 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761493926, COSV53773927; called by muse, mutect2, varscan2
- CYP2A6 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 152/391 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1488959980, COSV56534449; called by muse, mutect2, varscan2
- CYP3A43 | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV99733106; called by muse, mutect2, varscan2
- CYP4B1 | c.183C>T p.I61= | Splice Region (SNP) | VAF 91/187 reads (49%) | catalogued as COSV99597523; called by muse, mutect2, varscan2
- CYP4F2 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 108/296 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763027713, COSV55616039, COSV55618064; called by muse, varscan2
- CYP7B1 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1477692961; called by muse, mutect2, varscan2
- DBF4B | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs757573915; called by muse, mutect2, varscan2
- DCAF4L1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 71/120 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as COSV60787077; called by muse, mutect2, varscan2
- DDIAS | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV61271438; called by muse, mutect2, varscan2
- DDX47 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV61912128; called by muse, mutect2, varscan2
- DENND4A | c.5192C>T p.P1731L | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as rs761508769, COSV71265346; called by muse, mutect2, varscan2
- DENND4A | c.5191C>T p.P1731S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as rs764864062; called by muse, mutect2, varscan2
- DEPDC5 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 122/313 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs867743289, COSV56695845; called by muse, mutect2, varscan2
- DGAT2L6 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV60717511; called by muse, mutect2, varscan2
- DGAT2L6 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100284172; called by muse, mutect2, varscan2
- DLGAP2 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 117/274 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as COSV70100854; called by muse, mutect2, varscan2
- DNAH17 | c.9507G>A p.M3169I | Missense Mutation (SNP) | VAF 220/586 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV67757530; called by muse, mutect2
- DNAH3 | c.5641G>A p.E1881K | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.118); catalogued as COSV54520229; called by muse, mutect2, varscan2
- DNAH7 | c.8087C>T p.S2696F | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56768015; called by muse, mutect2, varscan2
- DNAH7 | c.4672G>A p.G1558R | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56780320; called by muse, mutect2, varscan2
- DNAH7 | c.3265C>T p.P1089S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs989543810; called by muse, mutect2, varscan2
- DNAJC5G | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV56080680, COSV56081314; called by muse, mutect2, varscan2
- DOCK4 | c.3602G>T p.R1201L | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs181180606; called by muse, mutect2, varscan2
- DPPA4 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 221/563 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as rs748894803, COSV59512523; called by muse, mutect2, varscan2
- DSC3 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112322768; called by muse, mutect2, varscan2
- DSG1 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 194/499 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57138627; called by muse, mutect2, varscan2
- DSG3 | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 111/303 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs907432395; called by muse, mutect2, varscan2
- DYNC2H1 | c.3457C>T p.R1153W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs544600765, COSV62091011; called by muse, mutect2, varscan2
- E4F1 | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 128/344 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs767312846, COSV57039187; called by muse, mutect2, varscan2
- EFEMP1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV62615606; called by muse, mutect2, varscan2
- EFHC2 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs760469358, COSV101375470, COSV69553493; called by muse, mutect2, varscan2
- EGFLAM | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 170/202 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1391989293; called by muse, mutect2, varscan2
- EHMT2 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV64997725; called by muse, mutect2, varscan2
- ELF1 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 79/111 reads (71%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs1218181125; called by muse, mutect2, varscan2
- ELL | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 117/268 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs759014608, COSV53211646; called by muse, mutect2, varscan2
- ELOA3 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 160/3130 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs748997785, COSV55293762; called by muse, mutect2
- ELP2 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1208233624; called by muse, mutect2, varscan2
- ENAM | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.263); catalogued as COSV68536004; called by muse, mutect2, varscan2
- EPHA1 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1389840241; called by muse, mutect2, varscan2
- EPHA2 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 128/313 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64452092, COSV64452513; called by muse, mutect2, varscan2
- EPHA5 | c.1927A>G p.K643E | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.366); catalogued as COSV99897373; called by muse, mutect2, varscan2
- EPHA7 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs138876328; called by muse, mutect2, varscan2
- EPM2AIP1 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 131/332 reads (39%) | catalogued as COSV51620433, COSV99212549; called by muse, mutect2, varscan2
- EPPK1 | c.6250C>T p.P2084S | Missense Mutation (SNP) | VAF 150/370 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.225); catalogued as rs781812162; called by muse, mutect2
- EPPK1 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 117/270 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200175131; called by muse, mutect2, varscan2
- EREG | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 34/85 reads (40%) | catalogued as rs376236920, COSV55262382; called by muse, mutect2, varscan2
- ERICH3 | c.4088C>T p.S1363L | Missense Mutation (SNP) | VAF 106/239 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751032690, COSV58619044; called by muse, mutect2, varscan2
- ETNK1 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as rs1425418403; called by muse, mutect2, varscan2
- EYS | c.2403G>A p.W801* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs1424625518; called by muse, mutect2, varscan2
- EYS | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 107/252 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100677217, COSV60984721; called by mutect2, varscan2
- EZH1 | c.2056C>T p.R686* | Nonsense Mutation (SNP) | VAF 64/170 reads (38%) | catalogued as rs1458266017, COSV52850540; called by muse, mutect2, varscan2
- F2RL3 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as rs372937570; called by muse, mutect2, varscan2
- FABP9 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as COSV66911396; called by muse, mutect2, varscan2
- FAM107B | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs1339748592, COSV99474222; called by muse, mutect2, varscan2
- FAM135B | c.3577C>T p.R1193W | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1180715939, COSV52715961, COSV99417794; called by muse, mutect2, varscan2
- FAM135B | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52718951, COSV52733976; called by muse, mutect2, varscan2
- FAM13C | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 153/380 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); catalogued as COSV53242843, COSV99513589; called by muse, mutect2, varscan2
- FAM149A | c.1730C>T p.S577L (on ENST00000356371 / NM_001367768.2; = p.S286L on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 155/398 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs762001214; called by muse, mutect2, varscan2
- FAM3D | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1332134866, COSV100717046; called by muse, mutect2, varscan2
- FAM71D | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.007); catalogued as rs769861811; called by muse, mutect2, varscan2
- FAM83B | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.489); catalogued as COSV60925973; called by muse, mutect2, varscan2
- FAM83B | c.1248G>A p.W416* | Nonsense Mutation (SNP) | VAF 42/98 reads (43%) | catalogued as rs779268613; called by muse, mutect2, varscan2
- FAM83B | c.3011G>A p.G1004E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs756470811, COSV60926764; called by muse, mutect2, varscan2
- FAP | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142146935, COSV51859814; called by muse, mutect2, varscan2
- FASN | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 221/532 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as rs762823912, COSV60752905; called by muse, mutect2, varscan2
- FASTKD2 | c.1880C>T p.S627F | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs1390288288; called by muse, mutect2, varscan2
- FAT2 | c.10978G>A p.D3660N | Missense Mutation (SNP) | VAF 77/133 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55814128; called by muse, mutect2, varscan2
- FAT3 | c.11401G>A p.E3801K | Missense Mutation (SNP) | VAF 164/436 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs1435237876, COSV53118159, COSV53159525; called by muse, mutect2, varscan2
- FAT4 | c.9487G>A p.E3163K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs370088878, CM1311052; called by muse, mutect2, varscan2
- FBH1 | c.923C>T p.P308L (on ENST00000362091 / NM_178150.3; = p.P359L on NM_032807.4) | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV100758963; called by muse, varscan2
- FBXO24 | c.211G>A p.E71K (on ENST00000241071 / NM_033506.3; = p.E109K on NM_012172.5) | Missense Mutation (SNP) | VAF 123/305 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs776297299, COSV53825559; called by muse, mutect2, varscan2
- FCGBP | c.9013C>T p.P3005S | Missense Mutation (SNP) | VAF 386/2859 reads (14%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.66); catalogued as rs748342735; called by muse, mutect2, varscan2
- FCRLA | c.448G>T p.E150* (on ENST00000367959; = p.E127* on NM_032738.4) | Nonsense Mutation (SNP) | VAF 115/297 reads (39%) | catalogued as rs781524210; called by muse, mutect2, varscan2
- FILIP1L | c.2586G>A p.W862* (on ENST00000354552 / NM_182909.3; = p.W622* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 41/121 reads (34%) | catalogued as COSV58776208; called by muse, mutect2, varscan2
- FLG | c.4687G>A p.E1563K | Missense Mutation (SNP) | VAF 228/583 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV100911527, COSV64242286; called by muse, varscan2
- FLG | c.4577G>A p.G1526E | Missense Mutation (SNP) | VAF 175/523 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as rs776816341, COSV64235652; called by muse, mutect2, varscan2
- FLNB | c.6976C>T p.P2326S | Missense Mutation (SNP) | VAF 143/397 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211837552; called by muse, mutect2, varscan2
- FLNC | c.5374G>A p.A1792T | Missense Mutation (SNP) | VAF 180/432 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201348102; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FLRT3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539605227; called by muse, mutect2, varscan2
- FMN2 | c.4402C>T p.R1468C | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs748812254, COSV100144530, COSV60425638; called by muse, mutect2, varscan2
- FOXK1 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 151/323 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.395); catalogued as rs1373940205; called by muse, mutect2, varscan2
- FREM1 | c.1713G>A p.M571I | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV66521139; called by muse, mutect2, varscan2
- FREM3 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as COSV61682661; called by muse, mutect2, varscan2
- FRMPD4 | c.1916T>A p.L639Q | Missense Mutation (SNP) | VAF 76/96 reads (79%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.099); catalogued as COSV66211893; called by muse, mutect2, varscan2
- FRY | c.6706C>T p.P2236S | Missense Mutation (SNP) | VAF 154/212 reads (73%) | SIFT tolerated (0.45); PolyPhen benign (0.145); catalogued as COSV66573682; called by muse, mutect2, varscan2
- FRY | c.6997G>A p.D2333N | Missense Mutation (SNP) | VAF 69/101 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs755355616; called by muse, mutect2, varscan2
- FSCN3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 97/301 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs768392595; called by muse, mutect2, varscan2
- FYB2 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs868085118; called by muse, mutect2, varscan2
- G6PC | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1555560217, COSV53832405; called by muse, mutect2, varscan2
- GABPB2 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as COSV64460494; called by muse, mutect2, varscan2
- GABRE | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 142/176 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs867877489, COSV100944370; called by muse, mutect2, varscan2
- GAK | c.3734G>A p.G1245E | Missense Mutation (SNP) | VAF 214/400 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs762130890, COSV58503374; called by muse, mutect2, varscan2
- GAK | c.3733G>A p.G1245R | Missense Mutation (SNP) | VAF 212/395 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779444679; called by muse, mutect2, varscan2
- GAL3ST4 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as rs1479748186; called by muse, mutect2, varscan2
- GALNT13 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 101/250 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101222185; called by muse, mutect2, varscan2
- GALNT17 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61148861; called by muse, mutect2, varscan2
- GALNT9 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 181/254 reads (71%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.537); catalogued as rs1303789264; called by muse, mutect2, varscan2
- GAPVD1 | c.3971G>A p.R1324Q (on ENST00000394104; = p.R1333Q on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/106 reads (72%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as rs376056156; called by muse, mutect2, varscan2
- GATA3 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 205/532 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV60522371; called by muse, mutect2, varscan2
- GBA | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs765693058; called by muse, mutect2, varscan2
- GBA3 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs373204012; called by muse, mutect2, varscan2
- GCKR | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 202/485 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs761397252, COSV53106414; called by muse, mutect2, varscan2
- GCNT7 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 94/252 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs550349236, COSV50129486; called by muse, mutect2, varscan2
- GCOM1 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147311786; called by muse, mutect2, varscan2
- GJA1 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 160/457 reads (35%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.646); catalogued as rs1265740574, COSV56997529; called by muse, mutect2, varscan2
- GJB2 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 130/196 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV101241508; called by muse, mutect2, varscan2
- GMNC | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as rs897912665; called by muse, mutect2, varscan2
- GNL3L | c.1390C>T p.H464Y | Missense Mutation (SNP) | VAF 64/89 reads (72%) | SIFT tolerated (0.4); PolyPhen benign (0.402); catalogued as rs1483034249; called by muse, mutect2, varscan2
- GOLGA8Q | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs1378199697; called by mutect2, varscan2
- GPR22 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.86); PolyPhen benign (0.026); catalogued as COSV51765150; called by muse, mutect2, varscan2
- GPR83 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV54718707, COSV54720284; called by muse, mutect2, varscan2
- GPRC6A | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775109241, COSV59951289; called by muse, mutect2, varscan2
- GRIA3 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52049378; called by muse, mutect2, varscan2
- GRIK2 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs1180999815, COSV59718133; called by muse, mutect2, varscan2
- GRIK2 | c.1610G>A p.G537E | Missense Mutation (SNP) | VAF 105/265 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59758807; called by muse, mutect2, varscan2
- GRIK3 | c.2655G>A p.M885I | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV100902135; called by muse, mutect2, varscan2
- GRM3 | c.1940G>A p.G647E | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs772318511; called by muse, mutect2, varscan2
- GSS | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 168/434 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.052); catalogued as rs763001933; called by muse, mutect2, varscan2
- GTF2IRD1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 98/249 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as rs139144176, COSV56086308; called by muse, mutect2, varscan2
- GZMM | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs1165398617, COSV52743364; called by muse, varscan2
- H1-6 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 142/388 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201733307; called by muse, mutect2, varscan2
- HDAC9 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs867599481, COSV67785345; called by muse, mutect2, varscan2
- HDAC9 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV67773418; called by muse, mutect2, varscan2
- HECW2 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs376126888; called by muse, mutect2, varscan2
- HERC2 | c.6115G>A p.V2039I | Missense Mutation (SNP) | VAF 277/882 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1378157705; called by muse, mutect2, varscan2
- HERC4 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.211); catalogued as COSV53269178; called by muse, mutect2, varscan2
- HERPUD2 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV60947843; called by muse, mutect2, varscan2
- HLA-DPA1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.542); catalogued as rs764514281, COSV70088498; called by muse, mutect2, varscan2
- HLA-DQB2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 90/320 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs746713265; called by muse, varscan2
- HMCN1 | c.8887C>T p.P2963S | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV54911523; called by muse, mutect2, varscan2
- HMCN1 | c.11536G>T p.V3846L | Missense Mutation (SNP) | VAF 95/234 reads (41%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.978); catalogued as rs1015938577; called by muse, mutect2, varscan2
- HNRNPU | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 252/671 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs570495195; called by muse, mutect2, varscan2
- HPCAL1 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1558537435, COSV100324165; called by muse, mutect2, varscan2
- HPR | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 111/158 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs367988509, COSV57184029; called by muse, mutect2, varscan2
- HSPG2 | c.2429C>T p.S810F | Missense Mutation (SNP) | VAF 142/362 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs1450403526; called by muse, mutect2, varscan2
- HYDIN | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1244006572; called by muse, mutect2, varscan2
- IGHG3 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 114/154 reads (74%) | SIFT tolerated (0.3); PolyPhen benign (0.192); catalogued as rs768763240; called by muse, mutect2, varscan2
- IGHV4-4 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 223/321 reads (69%) | catalogued as rs549396458; called by muse, mutect2, varscan2
- IGHV4-59 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 300/508 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.163); catalogued as rs782792143; called by muse, mutect2, varscan2
- IGKV1-39 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs780534208; called by mutect2, varscan2
- IGLV5-52 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs1363909807; called by muse, mutect2, varscan2
- IL1F10 | c.119-5C>T | Splice Region (SNP) | VAF 134/401 reads (33%) | catalogued as rs1256987546; called by muse, mutect2
- IL1RL1 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52118409, COSV52120584; called by muse, mutect2, varscan2
- IL21R | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV61973349; called by muse, mutect2, varscan2
- IQCE | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 130/359 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100383791; called by muse, mutect2, varscan2
- IRGC | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 123/282 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs759272396; called by muse, mutect2, varscan2
- ITGAV | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs559278598, COSV53709744; called by muse, mutect2, varscan2
- ITGAX | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 137/314 reads (44%) | catalogued as COSV51649266; called by muse, mutect2, varscan2
- ITPR1 | c.8069G>A p.G2690E (on ENST00000354582; = p.G2635E on NM_002222.7) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100233644; called by muse, mutect2, varscan2
- JADE2 | c.1610C>G p.S537W | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50921464; called by muse, mutect2, varscan2
- JAK3 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV71687973; called by muse, mutect2, varscan2
- JAKMIP1 | c.2455C>T p.L819F | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68956456; called by muse, mutect2, varscan2
- JMJD7 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 111/269 reads (41%) | catalogued as COSV59824184; called by muse, mutect2, varscan2
- JRK | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs781863311, COSV101401061; called by muse, mutect2, varscan2
- KCNB2 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050367; called by muse, mutect2, varscan2
- KCNC3 | c.2156G>A p.G719D | Missense Mutation (SNP) | VAF 142/299 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV65387059; called by muse, mutect2, varscan2
- KCNH7 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100147340; called by muse, mutect2
- KCNQ5 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59653227; called by muse, mutect2, varscan2
- KCTD16 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 170/247 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0.187); catalogued as COSV72577412; called by muse, mutect2, varscan2
- KDM4B | c.1516C>T p.L506F | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1447970270, COSV99347622; called by muse, mutect2, varscan2
- KDM5C | c.1168del p.R390Gfs*40 | Frame Shift Del (DEL) | VAF 180/282 reads (64%) | catalogued as COSV64769600; called by mutect2, pindel, varscan2
- KIAA1217 | c.5189C>T p.S1730L | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); catalogued as rs1189512254, COSV56812591; called by muse, mutect2, varscan2
- KIF13B | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769121640, COSV73054662; called by muse, mutect2, varscan2
- KIF14 | c.288G>T p.R96S | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV100950534; called by muse, mutect2, varscan2
- KIF17 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 152/349 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV99928242; called by muse, mutect2, varscan2
- KIF21B | c.3376G>A p.G1126S | Missense Mutation (SNP) | VAF 140/366 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.133); catalogued as rs1382480222; called by muse, mutect2, varscan2
- KIF26B | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV63654264; called by muse, mutect2, varscan2
- KIRREL1 | c.2033C>A p.T678K | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs201145714; called by muse, mutect2, varscan2
- KMT2B | c.5893C>T p.P1965S | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763584372; called by muse, mutect2, varscan2
- KMT2D | c.12413C>T p.S4138F | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1281537769, COSV56423898; called by muse, mutect2, varscan2
- KMT2D | c.7085C>T p.P2362L | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1220931991; called by muse, mutect2, varscan2
- KMT2E | c.3094C>T p.P1032S | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs754816791; called by muse, mutect2, varscan2
- KNSTRN | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51103388, COSV51103522; called by muse, mutect2, varscan2
- KRT222 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67499022; called by muse, mutect2, varscan2
- KRT4 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 140/373 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs770618586; called by muse, mutect2, varscan2
- KRT6A | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 111/398 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs1339399303; called by muse, mutect2, varscan2
- KRT79 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 251/526 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as COSV57942038; called by muse, mutect2, varscan2
- KRTAP9-9 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 262/676 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV101223552; called by muse, mutect2, varscan2
- KYAT3 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777248500, COSV53102002; called by muse, mutect2, varscan2
- L3MBTL1 | c.1201G>A p.E401K (on ENST00000418998 / NM_001377303.1; = p.E311K on NM_015478.7) | Missense Mutation (SNP) | VAF 119/281 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.824); catalogued as COSV64228887; called by muse, mutect2, varscan2
- LCORL | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1281283272; called by muse, mutect2, varscan2
- LCT | c.4132C>T p.P1378S | Missense Mutation (SNP) | VAF 165/367 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV51551548; called by muse, mutect2, varscan2
- LILRA4 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 128/314 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759751078, COSV52492084, COSV99393015; called by muse, mutect2, varscan2
- LIN28A | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 192/450 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV54262077; called by muse, mutect2, varscan2
- LIN9 | c.862C>T p.P288S (on ENST00000366808 / NM_001270410.2; = p.P233S on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs267598393, COSV60247060; called by muse, mutect2, varscan2
- LIPE | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54921680; called by muse, mutect2, varscan2
- LIPF | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.464); catalogued as rs1344968098; called by muse, mutect2, varscan2
- LMLN | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs778670724, COSV57604251; called by muse, mutect2, varscan2
- LPO | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764112101, COSV99229441; called by muse, mutect2, varscan2
- LRG1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 180/422 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as rs765306791, COSV56705348; called by muse, mutect2, varscan2
- LRIT2 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.564); catalogued as rs748493791; called by muse, mutect2, varscan2
- LRP1 | c.8128C>T p.P2710S | Missense Mutation (SNP) | VAF 78/146 reads (53%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.999); catalogued as COSV54511609; called by muse, mutect2, varscan2
- LRP1B | c.10282G>A p.E3428K | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67275491; called by muse, mutect2, varscan2
- LRP1B | c.7523C>T p.S2508F | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1393251553, COSV67193597; called by muse, mutect2, varscan2
- LRP2 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 138/328 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs766975916; called by muse, mutect2, varscan2
- LRRC3C | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100932483; called by muse, mutect2, varscan2
- LRRIQ1 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV67837634; called by muse, mutect2, varscan2
- LRRTM4 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 70/194 reads (36%) | catalogued as COSV69138907; called by muse, mutect2, varscan2
- LY75 | c.4484G>A p.G1495E | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV55101952; called by muse, mutect2, varscan2
- LY96 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs199845476; called by muse, mutect2, varscan2
- MACC1 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV60546206; called by muse, mutect2, varscan2
- MADCAM1 | c.830G>A p.G277D | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.145); catalogued as COSV53127478; called by muse, varscan2
- MAP2 | c.2017C>T p.L673F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.614); catalogued as rs370470543; called by muse, mutect2, varscan2
- MAP2K2 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 196/442 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as rs759998177, COSV99502601; called by muse, mutect2, varscan2
- MAP3K19 | c.1981G>A p.G661R | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs146312185; called by muse, mutect2, varscan2
- MAP3K6 | c.1140C>T p.H380= | Splice Region (SNP) | VAF 65/151 reads (43%) | catalogued as COSV62888903; called by muse, mutect2, varscan2
- MAP6 | c.2218C>T p.R740C | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1038563574, COSV59077721; called by muse, mutect2, varscan2
- MARCHF7 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV52029520; called by muse, mutect2, varscan2
- MARS1 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.013); catalogued as COSV56254909; called by muse, mutect2, varscan2
- MDN1 | c.8225C>T p.A2742V | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as rs774826637, COSV65517651; called by muse, mutect2, varscan2
- MDN1 | c.7309G>A p.D2437N | Missense Mutation (SNP) | VAF 189/421 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as COSV65527282; called by muse, mutect2, varscan2
- METRNL | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.226); catalogued as COSV60762148; called by muse, mutect2, varscan2
- MGAM | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.107); catalogued as rs1475463265, COSV71885216; called by muse, mutect2, varscan2
- MGAM | c.3655G>A p.G1219R | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99071111; called by muse, mutect2, varscan2
- MGAM | c.4289G>A p.G1430E | Missense Mutation (SNP) | VAF 128/368 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as rs1348650177, COSV72075846; called by muse, mutect2, varscan2
- MGAM2 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.093); catalogued as rs1469143931; called by muse, mutect2, varscan2
- MGLL | c.842C>T p.S281F (on ENST00000398104 / NM_001003794.2; = p.S291F on NM_007283.6) | Missense Mutation (SNP) | VAF 112/340 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54023933; called by muse, mutect2, varscan2
- MICB | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.158); catalogued as COSV52857346; called by muse, mutect2, varscan2
- MKI67 | c.7754C>T p.P2585L | Missense Mutation (SNP) | VAF 101/239 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.287); catalogued as rs138254987, COSV64077666; called by muse, mutect2, varscan2
- MLIP | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769959762, COSV51426013; called by muse, mutect2, varscan2
- MMP21 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1176673600; called by muse, mutect2, varscan2
- MMP9 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476025308; called by muse, mutect2, varscan2
- MMRN1 | c.929A>T p.Q310L | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as rs755892330; called by muse, mutect2, varscan2
- MOGAT2 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 195/398 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99549412; called by muse, mutect2, varscan2
- MPPE1 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 112/264 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1249049646; called by muse, mutect2, varscan2
- MPRIP | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 109/252 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs754649333; called by muse, mutect2, varscan2
- MRC2 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 138/302 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs765509790, COSV57640857; called by muse, mutect2, varscan2
- MSH4 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as COSV54197607; called by muse, mutect2, varscan2
- MSRB1 | c.204+8G>A | Splice Region (SNP) | VAF 167/429 reads (39%) | catalogued as rs889152936; called by muse, mutect2, varscan2
- MTMR3 | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 107/259 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1295984806, COSV100071480; called by muse, mutect2, varscan2
- MTMR7 | c.1328G>A p.S443N | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1484097457; called by muse, mutect2, varscan2
- MTPAP | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 103/262 reads (39%) | catalogued as rs773094167, COSV53934807; called by muse, mutect2, varscan2
- MUC16 | c.39589A>T p.S13197C | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV101109929; called by muse, mutect2, varscan2
- MUC16 | c.31817C>T p.T10606I | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV101199451; called by muse, mutect2, varscan2
- MUC16 | c.23108C>T p.S7703F | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV67451909; called by muse, mutect2, varscan2
- MUC16 | c.20876C>T p.S6959F | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as COSV67454402; called by muse, mutect2, varscan2
- MUC16 | c.18704C>T p.P6235L | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV67481556; called by muse, mutect2, varscan2
- MUC16 | c.16856G>A p.W5619* | Nonsense Mutation (SNP) | VAF 75/218 reads (34%) | catalogued as rs768465817; called by muse, mutect2, varscan2
- MUC3A | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious, low confidence (0); catalogued as rs754858120, COSV60225984; called by muse, varscan2
- MUC4 | c.6020C>T p.S2007F | Missense Mutation (SNP) | VAF 161/794 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1459168065, COSV62204726; called by muse, mutect2
- MXRA5 | c.6016G>A p.E2006K | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV54230410; called by muse, mutect2, varscan2
- MXRA5 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 80/98 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866233220, COSV54222468; called by muse, varscan2
- MXRA5 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 62/84 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99475959; called by muse, mutect2, varscan2
- MXRA8 | c.377-4G>A | Splice Region (SNP) | VAF 217/529 reads (41%) | catalogued as rs747801925; called by muse, mutect2, varscan2
- MYH1 | c.5216C>T p.S1739F | Missense Mutation (SNP) | VAF 99/250 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV56844579; called by muse, mutect2, varscan2
- MYH15 | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV56319856, COSV99843346; called by muse, mutect2, varscan2
- MYH9 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 170/455 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53393635; called by muse, mutect2, varscan2
- MYO1F | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 104/239 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57792606; called by muse, mutect2, varscan2
- MYO7A | c.4729G>A p.G1577R | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV68684711; called by muse, varscan2
- MYO7A | c.6052-1G>A p.X2018_splice | Splice Site (SNP) | VAF 35/66 reads (53%) | catalogued as rs752638379, COSV68684677; called by muse, mutect2, varscan2
- MYT1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as rs377464140; called by muse, varscan2
- NCR2 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV66101487; called by muse, mutect2, varscan2
- NDST4 | c.560A>T p.N187I | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52113970; called by muse, mutect2, varscan2
- NEB | c.18761G>A p.G6254E | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99426520; called by muse, mutect2, varscan2
- NEB | c.13144G>A p.E4382K | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs1479911719; called by muse, mutect2, varscan2
- NF1 | c.6687G>A p.W2229* (on ENST00000358273 / NM_001042492.3; = p.W2208* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 99/247 reads (40%) | catalogued as CM950850, COSV62212095; called by muse, mutect2, varscan2
- NF2 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 133/383 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as CD962106, COSV58530888; called by muse, mutect2, varscan2
- NFIA | c.92G>A p.W31* | Nonsense Mutation (SNP) | VAF 95/217 reads (44%) | catalogued as rs867909615; called by muse, mutect2, varscan2
- NINL | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV54003379; called by muse, mutect2, varscan2
- NKAIN4 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 117/329 reads (36%) | catalogued as COSV100941639; called by muse, mutect2, varscan2
- NLGN4Y | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 268/313 reads (86%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as rs907067999; called by muse, mutect2, varscan2
- NLRP12 | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 197/468 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1362127424, COSV60755339; called by muse, mutect2, varscan2
- NLRP2 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 95/229 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as rs776814479, COSV54759606; called by muse, mutect2, varscan2
- NLRP3 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1374519501; called by muse, mutect2, varscan2
- NLRP3 | c.2798G>A p.G933E | Missense Mutation (SNP) | VAF 106/282 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60230102; called by muse, mutect2, varscan2
- NLRP4 | c.1492T>A p.F498I | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs867737171; called by muse, mutect2, varscan2
- NLRP5 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as rs199737074; called by muse, mutect2, varscan2
- NNMT | c.446T>G p.L149R | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs769948100; called by muse, mutect2, varscan2
- NOBOX | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 147/347 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.041); catalogued as COSV56192875; called by muse, mutect2, varscan2
- NOL12 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs371438425; called by muse, mutect2, varscan2
- NOS2 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 90/191 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs754161294; called by muse, mutect2, varscan2
- NOS3 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 93/194 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as rs1490923378, COSV52491557; called by muse, mutect2, varscan2
- NOSTRIN | c.856G>A p.E286K (on ENST00000317647 / NM_001039724.4; = p.E208K on NM_052946.3) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV58320708; called by muse, mutect2
- NPAS4 | c.2222C>T p.S741L | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs267603127; called by muse, mutect2, varscan2
- NPIPB2 | c.845C>T p.P282L (on ENST00000399147; = p.P142L on NM_001355514.1) | Missense Mutation (SNP) | VAF 141/390 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs1222109967; called by mutect2, varscan2
- NPIPB4 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 81/555 reads (15%) | SIFT tolerated, low confidence (0.99); PolyPhen possibly damaging (0.649); catalogued as rs1312439263; called by muse, varscan2
- NRAP | c.4604C>T p.P1535L (on ENST00000359988 / NM_001322945.2; = p.P1500L on NM_006175.4) | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs921144685, COSV63490847; called by muse, varscan2
- NRG1 | c.1255C>T p.P419S (on ENST00000405005 / NM_013964.5; = p.P424S on NM_013956.5) | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772524774; called by muse, mutect2, varscan2
- NRG1 | c.1256C>T p.P419L (on ENST00000405005 / NM_013964.5; = p.P424L on NM_013956.5) | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181470222, COSV55177846; called by muse, mutect2, varscan2
- NRK | c.3158A>G p.E1053G | Missense Mutation (SNP) | VAF 145/173 reads (84%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs754400354; called by muse, mutect2, varscan2
- NRSN1 | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV101027310; called by muse, mutect2, varscan2
- NUGGC | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as rs955005459; called by muse, mutect2, varscan2
- NUGGC | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV58434848; called by muse, mutect2, varscan2
- NWD2 | c.4843C>T p.L1615F | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1380154390; called by muse, mutect2, varscan2
- OBP2B | c.75C>T p.I25= | Splice Region (SNP) | VAF 54/77 reads (70%) | catalogued as COSV100922814; called by muse, mutect2, varscan2
- OGDHL | c.2767C>T p.P923S | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867750245, COSV65101316; called by muse, mutect2, varscan2
- OGDHL | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65100582; called by muse, mutect2, varscan2
- OR10J3 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 102/246 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs868734843, COSV59953696, COSV59955976; called by muse, mutect2, varscan2
- OR1A2 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101126390; called by muse, mutect2, varscan2
- OR1F1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746066317, COSV100484439, COSV58961151; called by muse, mutect2, varscan2
- OR1Q1 | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 106/157 reads (68%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV99939206; called by muse, mutect2, varscan2
- OR1S2 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 99/296 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100224072; called by muse, varscan2
- OR2J2 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.251); catalogued as rs1204408586; called by muse, mutect2, varscan2
- OR2M3 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV71758951; called by muse, mutect2, varscan2
- OR2T34 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 104/358 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV60899740; called by muse, mutect2, varscan2
- OR4A15 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as COSV59037495; called by muse, mutect2, varscan2
- OR4C15 | c.817G>A p.V273I (on ENST00000314644; = p.V219I on NM_001001920.2) | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.098); catalogued as rs1367446619; called by muse, mutect2, varscan2
- OR4C16 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1256354622, COSV58940623, COSV58940762; called by muse, mutect2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 114/302 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2, varscan2
- OR5AP2 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs1486617293, COSV57259066; called by muse, mutect2, varscan2
- OR5B2 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.078); catalogued as COSV100222876; called by muse, mutect2, varscan2
- OR5D16 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as rs867879197, COSV65721582; called by muse, mutect2
- OR5I1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs766069607, COSV100041782, COSV56885194; called by muse, mutect2, varscan2
- OR5K2 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 110/240 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101415946; called by muse, mutect2, varscan2
- OR5M8 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 101/225 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV59116899; called by muse, mutect2, varscan2
- OR5T1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.049); catalogued as COSV57304969; called by muse, mutect2, varscan2
- OR8K3 | c.939A>T p.*313Yext*10 (on ENST00000641662; = p.*313Yext*? on NM_001005202.1) | Nonstop Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100449678, COSV57131983; called by muse, mutect2
- OR9G4 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs138033916; called by muse, mutect2, varscan2
- OSMR | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 186/216 reads (86%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as COSV57091926; called by muse, mutect2, varscan2
- OSMR | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 212/246 reads (86%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.644); catalogued as rs769344392, COSV57085792; called by muse, mutect2, varscan2
- OTOGL | c.3388C>T p.P1130S (on ENST00000547103; = p.P1121S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV101509062; called by muse, mutect2, varscan2
- OTOL1 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs866445322, COSV60006028, COSV60006472; called by muse, mutect2, varscan2
- OXCT2 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312803048; called by muse, varscan2
- P2RY2 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs755322202; called by muse, mutect2, varscan2
- PALD1 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 110/265 reads (42%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.763); catalogued as rs533752583; called by muse, mutect2, varscan2
- PALM3 | c.1603G>T p.E535* (on ENST00000340790; = p.E550* on NM_001145028.2) | Nonsense Mutation (SNP) | VAF 82/247 reads (33%) | catalogued as COSV54603103; called by muse, mutect2, varscan2
- PAPPA2 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 133/365 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0.017); catalogued as COSV62780972; called by muse, mutect2, varscan2
- PAPPA2 | c.2113G>A p.D705N | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs761015830; called by muse, mutect2, varscan2
- PAQR6 | c.609G>A p.R203= (on ENST00000292291 / NM_001272108.2; = p.R97= on NM_024897.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 82/190 reads (43%) | catalogued as COSV52744582; called by muse, mutect2, varscan2
- PARP15 | c.1276G>A p.D426N (on ENST00000464300 / NM_001113523.3; = p.D192N on NM_152615.2) | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs749555610, COSV59972128; called by muse, mutect2, varscan2
- PARP8 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 104/152 reads (68%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.163); catalogued as rs202205038, COSV55862044; called by muse, mutect2, varscan2
- PAX1 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1229986699; called by muse, mutect2, varscan2
- PBRM1 | c.3154C>T p.R1052* (on ENST00000296302 / NM_001366071.2; = p.R1027* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 42/58 reads (72%) | catalogued as COSV56260610; called by muse, mutect2, varscan2
- PCDH15 | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV57301613; called by muse, mutect2, varscan2
- PCDH18 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs868086398; called by muse, mutect2, varscan2
- PCDHA12 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 136/188 reads (72%) | catalogued as rs1554167756; called by muse, mutect2, varscan2
- PCDHB10 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 155/246 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53384662; called by muse, mutect2, varscan2
- PCDHGB3 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 82/137 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV53950994; called by muse, mutect2, varscan2
- PCK1 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1185656022; called by muse, mutect2, varscan2
- PCSK4 | c.731C>G p.S244W | Missense Mutation (SNP) | VAF 85/213 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766570695; called by muse, mutect2, varscan2
- PDCD10 | c.99A>G p.L33= | Splice Region (SNP) | VAF 76/209 reads (36%) | catalogued as rs369606517, COSV101208570; called by muse, varscan2
- PDE4A | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 130/261 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs758300846; called by muse, mutect2, varscan2
- PDE4B | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as rs1396000316, COSV100305699; called by muse, mutect2, varscan2
- PDZD3 | c.526G>A p.V176M (on ENST00000531114; = p.V110M on NM_024791.4) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs746197425; called by muse, mutect2, varscan2
- PDZD7 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.935); catalogued as COSV100932142; called by muse, mutect2, varscan2
- PDZRN4 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV68402795; called by muse, mutect2, varscan2
- PEG3 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as COSV55634402; called by muse, mutect2, varscan2
- PGM2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs201199256; called by muse, mutect2, varscan2
- PGM5 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 76/115 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.834); catalogued as rs782232692, COSV67167563; called by muse, mutect2, varscan2
- PHOX2B | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 202/324 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV56932016; called by muse, varscan2
- PHOX2B | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 217/362 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV56931113; called by muse, varscan2
- PICK1 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs895122027; called by muse, mutect2, varscan2
- PIK3C2G | c.3475G>A p.E1159K (on ENST00000676171; = p.E1118K on NM_004570.5) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.981); catalogued as COSV56815909; called by muse, mutect2, varscan2
- PIK3IP1 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53223442, COSV53223515; called by muse, mutect2, varscan2
- PIWIL2 | c.1715G>A p.R572K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs779755341, COSV63250459; called by muse, mutect2, varscan2
- PKHD1L1 | c.10151G>A p.G3384E | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV65744958; called by muse, mutect2, varscan2
- PLA2G4A | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV66557856; called by muse, mutect2, varscan2
- PLCE1 | c.3604G>A p.G1202R | Missense Mutation (SNP) | VAF 248/605 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752714644; called by muse, mutect2, varscan2
- PLCZ1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs1308051972, COSV56855967; called by muse, mutect2, varscan2
- POFUT1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 259/565 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as rs745383992, COSV65337185; called by muse, mutect2, varscan2
- POLD1 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1161281976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3B | c.3308C>T p.S1103F | Missense Mutation (SNP) | VAF 146/362 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV57278583; called by muse, mutect2, varscan2
- POPDC2 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs201668102; called by muse, mutect2, varscan2
- POTEH | c.1456C>G p.P486A | Missense Mutation (SNP) | VAF 117/604 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as rs1463585163; called by muse, varscan2
- PPBP | c.363G>C p.L121F | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779348146; called by muse, mutect2, varscan2
- PPDPFL | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1212695465, COSV57462436; called by muse, mutect2, varscan2
- PPM1E | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100376484; called by muse, mutect2, varscan2
- PPP1R3A | c.1994C>T p.S665L | Missense Mutation (SNP) | VAF 123/293 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52882141; called by muse, mutect2, varscan2
- PRAME | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 91/232 reads (39%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.52); catalogued as rs1023315891, COSV67162352; called by muse, mutect2
- PRB3 | c.914G>A p.G305E (on ENST00000381842; = p.G347E on NM_006249.5) | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as rs760108848, COSV99686085; called by muse, mutect2, varscan2
- PREX2 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs529924687, COSV55750983, COSV55758850; called by muse, mutect2, varscan2
- PRKACG | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 130/188 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760478735, COSV99599602; called by muse, mutect2, varscan2
- PRKAR2B | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1213025838; called by muse, mutect2, varscan2
- PRMT7 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 125/171 reads (73%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs529555935; called by muse, mutect2, varscan2
- PRODH2 | c.405C>T p.L135= (on ENST00000301175; = p.L59= on NM_021232.2 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 39/107 reads (36%) | catalogued as rs371889697; called by muse, mutect2
- PRR23C | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.025); catalogued as rs1248768056; called by muse, mutect2
- PRR33 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs796839221; called by muse, mutect2, varscan2
- PRSS35 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63801154; called by muse, mutect2, varscan2
- PSD | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs779421908; called by muse, mutect2, varscan2
- PTPN9 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 101/232 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs779716989; called by muse, mutect2, varscan2
- PTPRK | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781634717; called by muse, mutect2, varscan2
- PTPRN2 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 301/636 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV67030896; called by muse, mutect2, varscan2
- PTPRQ | c.4476G>A p.W1492* (on ENST00000616559; = p.W1450* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV57043844; called by muse, mutect2, varscan2
- PTPRR | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355830722, COSV51728664; called by muse, mutect2, varscan2
- PTPRT | c.2506G>A p.G836R | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs745346735, COSV100626660, COSV61982047; called by muse, mutect2
- PTPRT | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 124/257 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61973542; called by muse, mutect2, varscan2
- PWWP3B | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs781758273; called by muse, varscan2
- PXDNL | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 131/280 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV62496833; called by muse, mutect2, varscan2
- PXDNL | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 165/455 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.029); catalogued as COSV100685732; called by muse, mutect2
- PYGB | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 120/315 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs199655911; called by muse, mutect2, varscan2
- PZP | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54365693; called by muse, mutect2, varscan2
- RAG1 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 116/154 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100201043; called by muse, varscan2
- RAG1 | c.2615del p.L872* | Frame Shift Del (DEL) | VAF 84/164 reads (51%) | catalogued as rs1195836361; called by pindel, varscan2
- RASSF6 | c.409G>A p.D137N (on ENST00000342081 / NM_201431.2; = p.D105N on NM_177532.5) | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.737); catalogued as rs143969358, COSV56716501; called by muse, mutect2, varscan2
- RAVER2 | c.1520C>T p.T507I (on ENST00000294428 / NM_001366165.1; = p.T494I on NM_018211.4) | Missense Mutation (SNP) | VAF 103/321 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs761248241, COSV53805129; called by muse, mutect2, varscan2
- RB1CC1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50276735; called by muse, mutect2, varscan2
- RBBP8NL | c.398A>C p.K133T | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV53348499, COSV53349790; called by muse, mutect2, varscan2
- RBBP8NL | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 147/392 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs746142502; called by muse, varscan2
- RBM11 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs763112579, COSV68747915; called by muse, mutect2, varscan2
- RBMS2 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1444248926, COSV56263161; called by muse, mutect2, varscan2
- RCAN3 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV65558129; called by muse, mutect2, varscan2
- RELN | c.8984A>C p.Y2995S | Missense Mutation (SNP) | VAF 96/241 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100635016; called by muse, mutect2, varscan2
- RERG | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375905826, COSV57000887, COSV57001113; called by muse, mutect2, varscan2
- RFPL4A | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 158/597 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs374100254; called by muse, mutect2, varscan2
- RFTN1 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 206/469 reads (44%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV61921480; called by muse, mutect2, varscan2
- RFX3 | c.2137G>C p.E713Q | Missense Mutation (SNP) | VAF 239/329 reads (73%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.091); catalogued as COSV101137145; called by muse, mutect2, varscan2
- RGPD4 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs1323744127; called by muse, varscan2
- RHOV | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 118/322 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV55027433; called by muse, mutect2, varscan2
- RILPL2 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 72/97 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1022291437; called by muse, mutect2, varscan2
- RIT2 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 84/212 reads (40%) | catalogued as COSV56295413; called by muse, mutect2, varscan2
- RLF | c.4807C>T p.P1603S | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV65651464; called by muse, mutect2, varscan2
- RNF152 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 140/288 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV57185219; called by muse, mutect2, varscan2
- RNF213 | c.2353C>T p.P785S | Missense Mutation (SNP) | VAF 137/381 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.446); catalogued as rs760128593; called by muse, mutect2, varscan2
- ROBO1 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101458319; called by muse, mutect2, varscan2
- ROS1 | c.6443G>A p.G2148E | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100876896, COSV63851575; called by muse, mutect2, varscan2
- ROS1 | c.4238G>A p.G1413E | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63858077; called by muse, mutect2, varscan2
- RP1 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 162/394 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV55120407; called by muse, mutect2, varscan2
- RP1L1 | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 342/865 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.234); catalogued as rs529296323; called by muse, mutect2, varscan2
- RPS19BP1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 179/452 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1326469945; called by muse, mutect2, varscan2
- RUBCN | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.762); catalogued as COSV99065974; called by muse, mutect2, varscan2
- S1PR4 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as rs1484599320; called by muse, mutect2, varscan2
- SAFB2 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 142/378 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV53041958; called by muse, mutect2, varscan2
- SAMD3 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs763920331, COSV63717021; called by muse, mutect2, varscan2
- SAMD7 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 113/266 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs1449477565, COSV100156813; called by muse, mutect2, varscan2
- SATB1 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 102/276 reads (37%) | catalogued as COSV58672438; called by muse, mutect2, varscan2
- SCN10A | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV71861434; called by muse, varscan2
- SCN1A | c.3439G>A p.E1147K (on ENST00000303395 / NM_001202435.3; = p.E1136K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/301 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.415); catalogued as CM1311660; called by muse, mutect2, varscan2
- SCN3A | c.4550G>A p.G1517E | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99325710, COSV99326900; called by muse, mutect2, varscan2
- SCN7A | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.251); catalogued as rs1448558691, COSV69271113; called by muse, mutect2, varscan2
- SDK1 | c.5162C>T p.T1721M | Missense Mutation (SNP) | VAF 95/190 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs542998020, COSV67362658; called by muse, mutect2, varscan2
- SDK1 | c.5656T>C p.Y1886H | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV101270057; called by muse, mutect2, varscan2
- SEC14L6 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 114/301 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs760216929; called by muse, mutect2, varscan2
- SEC24C | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 94/261 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1210325582; called by muse, varscan2
- SEMA6D | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV60384559, COSV99054638; called by muse, mutect2, varscan2
- SEMG2 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV65647848; called by muse, mutect2, varscan2
- SEPTIN12 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs781297591, COSV51615640; called by muse, mutect2, varscan2
- SERPINB4 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as COSV100345837, COSV61984790; called by muse, mutect2, varscan2
- SETBP1 | c.1196A>T p.H399L | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV56335405; called by muse, mutect2, varscan2
- SFMBT2 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs759293227; called by muse, mutect2, varscan2
- SGPL1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV64590985; called by muse, mutect2, varscan2
- SGPL1 | c.1261A>G p.K421E | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs147607292; called by muse, varscan2
- SH2B2 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs782109422; called by muse, mutect2, varscan2
- SHOX2 | c.938C>T p.S313F (on ENST00000441443 / NM_006884.3; = p.S337F on NM_003030.4) | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs149542490, COSV101273767; called by muse, mutect2, varscan2
- SHPK | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 105/276 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs201999400; called by muse, mutect2, varscan2
- SHROOM4 | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 155/188 reads (82%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56789486; called by muse, mutect2, varscan2
- SIGLEC11 | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 131/544 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390186020; called by muse, mutect2, varscan2
- SIGLEC12 | c.629G>A p.G210E (on ENST00000291707 / NM_053003.4; = p.G92E on NM_033329.2) | Missense Mutation (SNP) | VAF 104/251 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV52466171; called by muse, mutect2, varscan2
- SIL1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 330/450 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs199921583; called by muse, mutect2, varscan2
- SIM1 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.073); catalogued as rs367796843, COSV53489580; called by muse, mutect2, varscan2
- SIRT2 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 167/417 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99979157; called by muse, mutect2, varscan2
- SLC12A8 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV58863488; called by muse, mutect2, varscan2
- SLC17A3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV57760736; called by muse, mutect2
- SLC22A25 | c.1400G>A p.R467K | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as rs781248283; called by muse, mutect2, varscan2
- SLC22A8 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1310792179, COSV100268091; called by muse, mutect2, varscan2
- SLC38A3 | c.1280A>G p.N427S | Missense Mutation (SNP) | VAF 58/69 reads (84%) | SIFT tolerated (0.64); PolyPhen benign (0.044); catalogued as rs767402083; called by muse, mutect2, varscan2
- SLC4A9 | c.2776G>A p.E926K (on ENST00000507527 / NM_001258428.2; = p.E902K on NM_031467.3) | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375734387; called by muse, mutect2
- SLC5A8 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867168951, COSV101610512, COSV73310407; called by muse, mutect2, varscan2
- SLC6A1 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 245/584 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55113723; called by muse, mutect2, varscan2
- SLC9A8 | c.1385T>G p.L462R | Missense Mutation (SNP) | VAF 174/400 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV64287607; called by muse, mutect2, varscan2
- SLCO1B3 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs148029725; called by muse, mutect2, varscan2
- SLCO1B3 | c.1003A>G p.N335D | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs758308277; called by muse, varscan2
- SMG6 | c.2891G>A p.R964H | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199692074; called by muse, mutect2, varscan2
- SMYD1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101352382; called by muse, mutect2, varscan2
- SNX31 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs765359363, COSV61261774; called by muse, mutect2, varscan2
- SORCS3 | c.1604G>A p.R535K | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1486626651, COSV63810895; called by muse, mutect2, varscan2
- SORL1 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 112/286 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867422963, COSV52757552; called by muse, mutect2, varscan2
- SORL1 | c.3769G>A p.D1257N | Missense Mutation (SNP) | VAF 123/351 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV52748721; called by muse, mutect2, varscan2
- SP140 | c.2096G>A p.G699E | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.568); catalogued as COSV59453655; called by muse, mutect2, varscan2
- SPAG17 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as rs755136638, COSV60463793; called by muse, varscan2
- SPAG17 | c.2705C>T p.S902F | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV60458429; called by muse, mutect2, varscan2
- SPANXD | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 147/191 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV65152280; called by muse, mutect2, varscan2
- SPEF2 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 73/80 reads (91%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs139870084, COSV56795893; called by muse, mutect2, varscan2
- SPEN | c.6722G>A p.G2241E | Missense Mutation (SNP) | VAF 118/319 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV65364012; called by muse, mutect2, varscan2
- SPICE1 | c.2411G>A p.G804E | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.744); catalogued as rs1416883878; called by muse, mutect2, varscan2
- SPINK8 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs767643652; called by muse, mutect2, varscan2
- SPIRE2 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 82/112 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs148431869; called by muse, mutect2, varscan2
- SPOCD1 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV57098698; called by muse, mutect2, varscan2
- SPPL2B | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 163/424 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs763351332, COSV71765562; called by muse, mutect2, varscan2
- SPTBN4 | c.7205C>T p.P2402L | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs970550719; called by muse, mutect2, varscan2
- SPTSSB | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.158); catalogued as COSV63218961; called by muse, mutect2, varscan2
- SRI | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99719739; called by muse, mutect2, varscan2
- SRRM2 | c.3103C>T p.L1035F | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.157); catalogued as rs372711925; called by muse, mutect2, varscan2
- SRRM2 | c.8008C>T p.P2670S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs747113957; called by muse, mutect2, varscan2
- SSBP3 | c.851C>T p.P284L (on ENST00000371320 / NM_145716.4; = p.P264L on NM_018070.5) | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as rs867968219; called by muse, mutect2, varscan2
- SSX1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 103/125 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV65356152; called by muse, mutect2, varscan2
- STAC | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.265); catalogued as rs144484309; called by muse, mutect2, varscan2
- STAC | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs775958676; called by muse, mutect2, varscan2
- STEAP3 | c.527G>C p.R176P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs763722603, COSV61527929, COSV61530346; called by muse, varscan2
- STOX1 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53818167; called by muse, mutect2, varscan2
- SUGP1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs1179685803; called by muse, mutect2, varscan2
- SUSD2 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771509280; called by muse, mutect2, varscan2
- SVEP1 | c.5407G>A p.E1803K | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs772505115; called by muse, mutect2, varscan2
- SYCP1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65694118, COSV65698105; called by muse, varscan2
- SYTL3 | c.1320C>A p.Y440* (on ENST00000611299 / NM_001242394.1; = p.Y372* on NM_001009991.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 109/141 reads (77%) | catalogued as COSV51916175; called by muse, mutect2, varscan2
- TAAR5 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs766614989, COSV57799479, COSV57799510; called by muse, mutect2, varscan2
- TADA2B | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as rs765043583; called by muse, mutect2, varscan2
- TAS1R1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV60226895; called by muse, mutect2, varscan2
- TBC1D16 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs757671771; called by muse, mutect2, varscan2
- TCEA3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.094); catalogued as COSV65840931; called by muse, mutect2, varscan2
- TCHH | c.2882G>T p.R961L | Missense Mutation (SNP) | VAF 130/376 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as COSV104425439; called by muse, mutect2, varscan2
- TCTE1 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 172/490 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as rs748939646, COSV101025380; called by muse, varscan2
- TDRD5 | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 130/317 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs1437730414, COSV54249461; called by muse, mutect2, varscan2
- TECTA | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 201/507 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.271); catalogued as rs867836820, COSV50691680, COSV50779839; called by muse, mutect2, varscan2
- TEKT4 | c.1052G>C p.R351P | Missense Mutation (SNP) | VAF 134/298 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54624529, COSV54625971; called by muse, mutect2, varscan2
- TENM2 | c.2176G>A p.D726N (on ENST00000518659 / NM_001122679.2; = p.D494N on NM_001080428.3) | Missense Mutation (SNP) | VAF 138/171 reads (81%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as rs769802847, COSV69122426, COSV69137524; called by muse, mutect2, varscan2
- TENM4 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs767456713; called by muse, mutect2, varscan2
- TENM4 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 192/501 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1390179278; called by muse, mutect2, varscan2
- TEX13C | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 138/163 reads (85%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1225805497, COSV67111579; called by muse, mutect2, varscan2
- TEX15 | c.3349C>T p.H1117Y (on ENST00000256246; = p.H1500Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.563); catalogued as rs1049652912; called by muse, mutect2, varscan2
- TFCP2 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.608); catalogued as rs1393478850; called by muse, mutect2, varscan2
- TFEC | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs753105593, COSV55407446; called by muse, mutect2, varscan2
- TGM1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 201/265 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778635368, CM981914, COSV52863300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THSD7B | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99754968; called by muse, varscan2
- THSD7B | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 89/212 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV55739229; called by muse, varscan2
- TIE1 | c.3007G>A p.G1003R | Missense Mutation (SNP) | VAF 110/323 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV65250685; called by muse, mutect2, varscan2
- TIMM21 | c.364+2T>C p.X122_splice | Splice Site (SNP) | VAF 56/160 reads (35%) | catalogued as rs1271514922; called by muse, mutect2, varscan2
- TLR4 | c.1779G>A p.W593* (on ENST00000355622 / NM_138554.5; = p.W553* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 66/95 reads (69%) | catalogued as rs5030720; called by muse, mutect2, varscan2
- TM6SF1 | c.399G>A p.E133= | Splice Region (SNP) | VAF 35/94 reads (37%) | catalogued as rs1452306728; called by muse, mutect2, varscan2
- TMEM126A | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0.251); catalogued as rs991954040; called by muse, mutect2, varscan2
- TMEM132C | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as rs868168045; called by muse, mutect2, varscan2
- TMEM200A | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51657240; called by muse, varscan2
- TMEM207 | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as rs754752355; called by muse, mutect2, varscan2
- TMEM94 | c.3682G>A p.G1228R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV58595772; called by muse, mutect2, varscan2
- TMPRSS13 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1239296662, COSV70626420; called by muse, mutect2
- TMPRSS4 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 91/258 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.722); catalogued as rs200645289; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs748106478, COSV100925350; called by muse, mutect2, varscan2
- TNS2 | c.762-5C>T | Splice Region (SNP) | VAF 78/188 reads (41%) | catalogued as rs1431650911; called by muse, mutect2, varscan2
- TNXB | c.9166G>A p.E3056K (on ENST00000647633; = p.E2809K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs1046018971, COSV64477366, COSV64486489, COSV64487656; called by muse, mutect2, varscan2
- TP63 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.885); catalogued as rs754361670, COSV53209193, COSV53218266; called by muse, mutect2, varscan2
- TRANK1 | c.7162C>T p.R2388C | Missense Mutation (SNP) | VAF 108/292 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57159986; called by muse, mutect2, varscan2
- TRAT1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV55469431; called by muse, mutect2, varscan2
- TRDN | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as rs867777177, COSV62116318; called by muse, varscan2
- TREX2 | c.503C>T p.P168L (on ENST00000334497; = p.P125L on NM_080701.3) | Missense Mutation (SNP) | VAF 88/101 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781868111; called by muse, mutect2, varscan2
- TRIM46 | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 217/604 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.344); catalogued as rs867177514; called by muse, mutect2, varscan2
- TRIM71 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 89/179 reads (50%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.843); catalogued as rs200204603; called by muse, mutect2, varscan2
- TRPC1 | c.1462G>A p.D488N (on ENST00000476941 / NM_001251845.2; = p.D454N on NM_003304.4) | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV56425128; called by muse, mutect2, varscan2
- TRPV4 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 186/511 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs546287338; called by muse, mutect2, varscan2
- TSC2 | c.2967-8C>T | Splice Region (SNP) | VAF 149/367 reads (41%) | catalogued as rs1060504085; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSSK1B | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 122/154 reads (79%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); catalogued as rs868567777; called by muse, mutect2, varscan2
- TTBK2 | c.2974C>T p.L992F | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV51157357; called by muse, mutect2, varscan2
- TTC28 | c.4160C>T p.S1387L | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs1320669216, COSV67413004; called by muse, mutect2, varscan2
- TTN | c.78868G>A p.E26290K (on ENST00000591111; = p.E18866K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | PolyPhen possibly damaging (0.554); catalogued as rs752902445; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.75731C>T p.P25244L (on ENST00000591111; = p.P17820L on NM_003319.4) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | PolyPhen benign (0.075); catalogued as rs1208813595, COSV60327695; called by muse, mutect2, varscan2
- TTN | c.69922G>A p.E23308K (on ENST00000591111; = p.E15884K on NM_003319.4) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | PolyPhen possibly damaging (0.654); catalogued as COSV59888493; called by muse, mutect2, varscan2
- TTN | c.28555G>A p.E9519K (on ENST00000591111; = p.E8592K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | PolyPhen probably damaging (0.994); catalogued as COSV60115852; called by muse, mutect2, varscan2
- TTN | c.3285A>C p.E1095D (on ENST00000591111; = p.E1049D on NM_003319.4) | Missense Mutation (SNP) | VAF 204/548 reads (37%) | PolyPhen probably damaging (0.99); catalogued as rs372103803; called by muse, mutect2, varscan2
- UBE3B | c.3101C>T p.S1034F | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1197725620; called by muse, mutect2, varscan2
- UFL1 | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs138835062; called by muse, mutect2, varscan2
- UGT1A6 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 107/351 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as COSV100530011; called by muse, mutect2, varscan2
- UGT1A6 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 108/351 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs116011063, COSV59401146; called by muse, mutect2, varscan2
- UGT2A3 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 112/275 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as rs369449006; called by muse, mutect2, varscan2
- UGT2B7 | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 105/231 reads (45%) | catalogued as rs752860546; called by muse, mutect2, varscan2
- UNC13C | c.5821G>A p.G1941R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs559979535, COSV52858488; called by muse, mutect2, varscan2
- UNC80 | c.7984C>T p.H2662Y | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.979); catalogued as COSV99072500; called by muse, mutect2, varscan2
- USH2A | c.15297+1G>A p.X5099_splice | Splice Site (SNP) | VAF 83/122 reads (68%) | catalogued as rs767630412; called by muse, mutect2, varscan2
- USH2A | c.9154G>A p.E3052K | Missense Mutation (SNP) | VAF 95/120 reads (79%) | SIFT tolerated (0.21); PolyPhen benign (0.335); catalogued as COSV56382138; called by muse, mutect2, varscan2
- USH2A | c.3862G>A p.E1288K | Missense Mutation (SNP) | VAF 68/96 reads (71%) | SIFT tolerated (0.48); PolyPhen benign (0.412); catalogued as COSV56361456, COSV56406558; called by muse, mutect2, varscan2
- USP43 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.561); catalogued as COSV53306037; called by muse, mutect2, varscan2
- VN1R5 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs866515821; called by muse, mutect2, varscan2
- VPS41 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs374797652; called by muse, mutect2, varscan2
- WDFY4 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 110/270 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.51); catalogued as rs1490165480; called by muse, mutect2, varscan2
- WDFY4 | c.6865G>A p.D2289N | Missense Mutation (SNP) | VAF 95/255 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1423191657, COSV99630593; called by muse, mutect2, varscan2
- WDFY4 | c.7039G>A p.E2347K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs565241222, COSV55436109; called by muse, mutect2, varscan2
- WFIKKN2 | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 144/304 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs758406365, COSV60958676; called by muse, mutect2, varscan2
- WNK2 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 150/214 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV52941103; called by muse, mutect2, varscan2
- WNT8A | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 58/83 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64230821; called by muse, mutect2, varscan2
- XDH | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV65146715; called by muse, mutect2, varscan2
- XIRP2 | c.1151C>T p.S384L (on ENST00000628543; = p.S559L on NM_152381.6) | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.058); catalogued as rs749943076, COSV54726771; called by muse, mutect2, varscan2
- XIRP2 | c.1274C>T p.S425F (on ENST00000628543; = p.S600F on NM_152381.6) | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.365); catalogued as COSV54723971; called by muse, mutect2, varscan2
1,899 further variants in this file (786 protein-altering or splice-affecting, 780 silent, 333 other) are not listed here.
